Somatic mutation profile of tumor specimen ALCH-AELS-TTP1-A (aliquot ALCH-AELS-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AELS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,879 days).
Specimen ALCH-AELS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c16ad4-1bd3-4a9a-9b79-630acf518bf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELS-NB1-A (Blood Derived Normal), aliquot ALCH-AELS-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee0195e3-d0b3-47e8-a3fc-b3ad5d78e59b

The open-access MAF lists 89 somatic variants for this specimen: 64 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 15, Intron 5, Frame Shift Del 5, 3'UTR 3, RNA 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1886del p.L629* | Frame Shift Del (DEL) | VAF 94/677 reads (14%) | catalogued as rs863224817; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC9 | c.3634C>T p.L1212F | Missense Mutation (SNP) | VAF 19/707 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV53969122; called by muse, mutect2
- BBC3 | c.443del p.G148Afs*81 (on ENST00000449228 / NM_001127240.3; = p.A114Lfs*101 on NM_014417.5) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1568623329; called by mutect2, pindel, varscan2
- BSN | c.2920C>T p.R974C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779247950; called by muse, mutect2, varscan2
- ERG | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs993206522, COSV55728066; called by muse, mutect2
- FBXL20 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs775705789; called by muse, mutect2, varscan2
- FCGBP | c.11366A>G p.N3789S | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751961693; called by muse, mutect2, varscan2
- FLNC | c.4706C>T p.A1569V | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1407018839, COSV57951019; called by muse, mutect2
- FLNC | c.6608G>A p.R2203H | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.379); catalogued as rs1063262, COSV57955678; called by muse, mutect2, varscan2
- GNAS | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs766422930, COSV58332649; called by muse, mutect2, varscan2
- KRTAP10-3 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs376857760; called by muse, varscan2
- KRTAP19-2 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 28/589 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.937); catalogued as COSV100477661; called by muse, mutect2
- LPIN2 | c.2358C>G p.F786L | Missense Mutation (SNP) | VAF 66/680 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55241917; called by muse, mutect2
- LRGUK | c.1952G>A p.W651* | Nonsense Mutation (SNP) | VAF 41/237 reads (17%) | catalogued as rs1425955290, COSV99603961; called by muse, mutect2, varscan2
- LRP5 | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as CM076268, COSV53713917; called by muse, mutect2
- LURAP1L | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179729389; called by muse, mutect2
- MMP27 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52780561; called by muse, mutect2, varscan2
- MTMR14 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as COSV99931666; called by muse, mutect2
- NAA50 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.951); catalogued as rs376468271; called by muse, mutect2, varscan2
- NYNRIN | c.3710G>T p.R1237L | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV66841803; called by muse, mutect2, varscan2
- OR4B1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 49/453 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs780047019, COSV100535710, COSV58883728; called by muse, mutect2, varscan2
- PHOSPHO1 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs772698351, COSV99865549; called by muse, mutect2, varscan2
- RIMS2 | c.3857del p.G1286Afs*7 | Frame Shift Del (DEL) | VAF 33/281 reads (12%) | catalogued as COSV51701223; called by mutect2, pindel, varscan2
- RNMT | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV51084939; called by muse, mutect2, varscan2
- SLC16A14 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.661); catalogued as rs868007529, COSV99725422; called by muse, mutect2
- TTC7A | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs199513496, COSV55408799; called by muse, mutect2, varscan2
- VTI1A | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 56/501 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67581825; called by muse, mutect2, varscan2
- ABCA10 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- ANKRD52 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.1); called by muse, mutect2
- ANKRD52 | c.28-1G>C p.X10_splice | Splice Site (SNP) | VAF 9/217 reads (4%) | called by muse, mutect2
- AP3B2 | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP28 | c.2148T>A p.N716K (on ENST00000383472 / NM_001366230.1; = p.N557K on NM_001010000.3) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGEF6 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 62/577 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- BTAF1 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDK13 | c.2464A>C p.M822L | Missense Mutation (SNP) | VAF 16/517 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.174); called by muse, mutect2
- COCH | c.1823G>C p.R608T (on ENST00000216361 / NM_001347720.1; = p.R543T on NM_004086.3) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- COL12A1 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CTNND2 | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2
- CTR9 | c.42C>G p.D14E | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2
- DCP2 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F8 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 60/629 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FRY | c.4673C>G p.S1558C | Missense Mutation (SNP) | VAF 59/508 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, varscan2
- GNPAT | c.1238A>C p.K413T | Missense Mutation (SNP) | VAF 75/618 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- GSDMA | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IFNA2 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 16/385 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2
- L3MBTL4 | c.1149del p.C384Afs*4 | Frame Shift Del (DEL) | VAF 29/263 reads (11%) | called by mutect2, pindel, varscan2
- LAMA2 | c.7019C>T p.T2340I | Missense Mutation (SNP) | VAF 23/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- LOXHD1 | c.5092C>T p.H1698Y (on ENST00000642948; = p.H587Y on NM_001145472.3) | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- LTBP2 | c.4499del p.G1500Afs*68 | Frame Shift Del (DEL) | VAF 98/589 reads (17%) | called by mutect2, pindel, varscan2
- MARCO | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MEP1A | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); called by muse, mutect2
- MRTFB | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 26/700 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- MTOR | c.4562G>C p.W1521S | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MUC5AC | c.15982C>T p.P5328S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- NLRP2 | c.2840A>C p.E947A | Missense Mutation (SNP) | VAF 24/682 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- OR5AC2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBXIP1 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2
- SARDH | c.2134C>G p.H712D | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TEX35 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRBV24-1 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); called by muse, mutect2
- UGT2B28 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 24/563 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- WBP4 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF200 | c.865T>G p.F289V | Missense Mutation (SNP) | VAF 21/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- ZNF595 | c.1416A>C p.K472N | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2
- CHST3 | c.927G>A p.S309= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs1013851768, COSV64151228; called by muse, mutect2, varscan2
- DCAF4L1 | c.612G>A p.L204= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- DYNLRB2 | c.48G>T p.G16= | Silent (SNP) | VAF 68/425 reads (16%) | catalogued as COSV58416405; called by muse, mutect2, varscan2
- ERCC6L | c.2673T>C p.R891= | Silent (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- FAR1 | c.759C>G p.L253= | Silent (SNP) | VAF 38/377 reads (10%) | catalogued as rs1387286578; called by muse, mutect2
- FBN2 | c.6228A>T p.P2076= | Silent (SNP) | VAF 106/480 reads (22%) | called by muse, mutect2, varscan2
- NOL4 | c.270C>T p.G90= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1456625959, COSV52346284; called by muse, mutect2
- NTN5 | c.1356G>A p.A452= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- NUP160 | c.1896A>T p.L632= | Silent (SNP) | VAF 40/333 reads (12%) | catalogued as COSV65854089; called by muse, mutect2, varscan2
- OVCH1 | c.405T>C p.Y135= | Silent (SNP) | VAF 21/434 reads (5%) | called by muse, mutect2
- RHBG | c.33G>C p.R11= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as rs1432915997; called by muse, mutect2, varscan2
- SPANXN1 | c.201G>A p.L67= | Silent (SNP) | VAF 51/452 reads (11%) | catalogued as COSV65123400; called by muse, mutect2, varscan2
- TAF1L | c.5325T>C p.D1775= | Silent (SNP) | VAF 24/566 reads (4%) | catalogued as COSV54268860; called by muse, mutect2
- TAS1R2 | c.1383C>T p.P461= | Silent (SNP) | VAF 55/411 reads (13%) | called by muse, mutect2, varscan2
- UACA | c.4053G>A p.R1351= | Silent (SNP) | VAF 28/312 reads (9%) | catalogued as rs755161566; called by muse, mutect2
- AC235097.1 | n.419A>C | RNA (SNP) | VAF 16/255 reads (6%) | called by muse, mutect2
- CACNA1B | c.530+9496C>T | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as rs866711025; called by muse, mutect2
- LCN1 | c.*113C>T | 3'UTR (SNP) | VAF 6/84 reads (7%) | catalogued as rs1022734574; called by muse, mutect2
- MAP2K2 | c.1046+34G>A | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as rs561722470; called by mutect2, varscan2
- NDUFS7 | c.123-79C>T | Intron (SNP) | VAF 15/82 reads (18%) | catalogued as rs763612447; called by muse, mutect2, varscan2
- NELFA | c.668-49A>C | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- P2RX5 | c.*41C>A | 3'UTR (SNP) | VAF 39/398 reads (10%) | called by muse, mutect2
- SLC13A2 | c.232-109_232-108insT | Intron (INS) | VAF 8/81 reads (10%) | called by mutect2, pindel, varscan2
- TULP3 | c.*1090T>C | 3'UTR (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- WASF4P | n.1060T>C | RNA (SNP) | VAF 13/232 reads (6%) | called by muse, mutect2
